Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3560, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3560-01A (Primary Tumor).

Diagnosis:

Resected colon (sigma) with tumor-free oral and aboral resection margins, including a hyperplastic polyp and several tubular adenoma with mild to moderate dysplasia (synonymously: mild intraepithelial neoplasia) and with an ulcerated, moderately differentiated adenocarcinoma with infiltration of the perimuscular adipose tissue and with several lymph node metastases in the region (G2, pT3, L1, V0, local R0, pN2, 5/25).

Source: NCI Genomic Data Commons file 45dadf2a-1b96-4154-a0a0-dfb43992af0a (TCGA-AA-3560.51DACDFD-6FD2-472D-89C3-A46FD0A50084.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).